Somatic mutation profile of tumor specimen TCGA-CV-A45X-01A (aliquot TCGA-CV-A45X-01A-21D-A25D-08) from TCGA case TCGA-CV-A45X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.8 years (17,464 days).
Specimen TCGA-CV-A45X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb2ba38-aea4-411f-ad28-73fedd5d0c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45X-10A (Blood Derived Normal), aliquot TCGA-CV-A45X-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed7de197-fa5a-44b6-8e84-a9ef780028c0

The open-access MAF lists 121 somatic variants for this specimen: 83 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 37, Nonsense Mutation 5, Splice Site 4, In Frame Del 2, Splice Region 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.2848G>T p.G950C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57899356; called by muse, mutect2, varscan2
- AHNAK2 | c.4085T>G p.M1362R | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs775038003, COSV100318961; called by muse, mutect2, varscan2
- ASCC3 | c.1549A>T p.I517F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100226358; called by muse, mutect2, varscan2
- BAZ2B | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1310895430, COSV100601014; called by muse, mutect2
- BMP3 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV99261621, COSV99262050; called by muse, mutect2, varscan2
- C10orf90 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1205717298, COSV99505102; called by muse, mutect2, varscan2
- C12orf4 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99712946; called by muse, mutect2, varscan2
- C15orf39 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs79122600, COSV100641476; called by muse, mutect2
- CD200R1L | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142953807, COSV68004161; called by muse, mutect2, varscan2
- CNTN3 | c.762T>C p.N254= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99726088; called by muse, mutect2, varscan2
- CNTNAP1 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99227017; called by muse, mutect2, varscan2
- CPEB2 | c.2797A>G p.I933V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV99470698; called by muse, mutect2, varscan2
- CYP2D6 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs967434863, COSV100637382; called by muse, mutect2
- DNAH7 | c.6253G>A p.D2085N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1205085053, COSV100417578; called by muse, mutect2, varscan2
- DNAJB11 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV54003294, COSV99408749; called by muse, mutect2
- DSTYK | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs202242580, COSV100904717; called by mutect2, varscan2
- ENPP1 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); catalogued as COSV100719648; called by muse, mutect2, varscan2
- EPB41L4A | c.841T>A p.C281S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99814124; called by muse, mutect2, varscan2
- FAM153B | c.904G>A p.V302I (on ENST00000253490; = p.V225I on NM_001265615.1) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.198); catalogued as rs1439523964; called by muse, mutect2
- FAM214A | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV99957603; called by muse, mutect2, varscan2
- FGG | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100272085; called by muse, mutect2, varscan2
- FLNA | c.3460G>A p.V1154M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1557177750, COSV100775252; called by muse, mutect2, varscan2
- FPGT | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100907540; called by muse, mutect2
- GRIP1 | c.1691C>A p.S564Y (on ENST00000359742 / NM_001379345.1; = p.S512Y on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99670870; called by muse, mutect2, varscan2
- HMCN1 | c.1777G>C p.V593L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99635833; called by muse, mutect2
- HNRNPA1L2 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as rs1369036657; called by muse, mutect2
- HRNR | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs537545646, COSV100913958; called by muse, mutect2, varscan2
- ITSN2 | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100744174; called by muse, mutect2, varscan2
- KRTAP5-6 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | catalogued as COSV101191776; called by muse, mutect2, varscan2
- LYPD3 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV99747248; called by muse, mutect2, varscan2
- MAP4K2 | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99581745; called by muse, mutect2, varscan2
- MAST3 | c.2854G>A p.V952I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs200457728, COSV53218248; called by muse, mutect2, varscan2
- MFSD1 | c.652+2T>C p.X218_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99964086; called by muse, mutect2, varscan2
- MTOR | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100816659; called by muse, mutect2, varscan2
- NAP1L3 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100220686; called by muse, mutect2, varscan2
- NCKAP1 | c.1895A>G p.H632R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1172339696, COSV100720558; called by muse, mutect2, varscan2
- NME8 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99553855; called by muse, mutect2
- NOD1 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs1204304547, COSV99768497; called by muse, mutect2
- NOL4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs757148536, COSV52338009; called by muse, mutect2, varscan2
- NSD3 | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs993754552, COSV100395763; called by muse, mutect2, varscan2
- NSD3 | c.2115+2T>A p.X705_splice | Splice Site (SNP) | VAF 21/175 reads (12%) | catalogued as COSV100388929; called by muse, mutect2, varscan2
- NXF5 | n.1166A>T | Splice Region (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99534666; called by muse, mutect2, varscan2
- OR11H12 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs754036492, COSV101612532; called by muse, mutect2, varscan2
- OR2M5 | c.703C>G p.R235G | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100822886, COSV63545660; called by muse, mutect2, varscan2
- OR2T1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs369905309, COSV63541982; called by muse, mutect2
- OTUD7A | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100193262; called by muse, mutect2, varscan2
- PARP6 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 144/391 reads (37%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV99536380; called by muse, mutect2, varscan2
- PCNT | c.9563T>A p.I3188N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100856037; called by muse, mutect2, varscan2
- PDZRN4 | c.2245C>A p.P749T (on ENST00000402685 / NM_001164595.2; = p.P491T on NM_013377.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100115472; called by muse, mutect2, varscan2
- PLA2G6 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100140723; called by muse, mutect2, varscan2
- PLPPR4 | c.2257A>C p.K753Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100926937; called by muse, mutect2, varscan2
- PLS3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99172320; called by muse, mutect2, varscan2
- PMF1 | c.565-1G>T p.X189_splice | Splice Site (SNP) | VAF 26/124 reads (21%) | catalogued as COSV99431627; called by muse, mutect2, varscan2
- PPM1B | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99175912; called by muse, mutect2, varscan2
- PPP1CA | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs760799660, COSV100335069; called by muse, mutect2, varscan2
- PSPC1 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100142669; called by muse, mutect2
- RARB | c.731A>T p.K244I (on ENST00000383772 / NM_001290216.2; = p.K237I on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58064874; called by muse, mutect2
- RARG | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100553698; called by muse, mutect2, varscan2
- RASGRP2 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100818355; called by muse, mutect2, varscan2
- RGL1 | c.2102T>C p.V701A (on ENST00000360851 / NM_001297672.2; = p.V736A on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV100487764; called by muse, mutect2, varscan2
- RPGRIP1L | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs201312119; called by mutect2, varscan2
- RTP2 | c.152A>C p.H51P | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100833027; called by muse, mutect2, varscan2
- SLC5A9 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99361996; called by mutect2, varscan2
- SMCHD1 | c.4420C>G p.L1474V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99862596; called by muse, mutect2, varscan2
- SORCS1 | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV99550373; called by muse, mutect2, varscan2
- SORCS3 | c.2892C>A p.S964R | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100863829; called by muse, mutect2, varscan2
- TARS1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV99466479; called by muse, mutect2
- TAX1BP1 | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99604840; called by muse, mutect2, varscan2
- TCTN3 | c.602C>G p.T201S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV99797625; called by muse, mutect2, varscan2
- TENM1 | c.2901G>C p.Q967H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100950457, COSV100950967; called by muse, mutect2, varscan2
- UGGT2 | c.2309A>T p.H770L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100948952; called by muse, mutect2, varscan2
- ULK4 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100095345; called by muse, mutect2, varscan2
- ZBTB25 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as rs866861977, COSV101170755; called by muse, mutect2, varscan2
- ZBTB37 | c.242A>G p.E81G | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100774649; called by muse, mutect2
- ZFY | c.425A>T p.H142L | Missense Mutation (SNP) | VAF 100/154 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.243); catalogued as COSV99324293; called by muse, mutect2, varscan2
- ZFYVE21 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs760873429, COSV99162378; called by muse, mutect2, varscan2
- ZIC3 | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1365863941, COSV99799509; called by muse, mutect2
- ZNF347 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV100498446; called by muse, mutect2, varscan2
- PIBF1 | c.1374dup p.Q459Sfs*3 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- PTPRB | c.1216_1236del p.E406_L412del | In Frame Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- SCRN3 | c.1191_1202del p.E397_N401delinsD | In Frame Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- TRAV6 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- AP5Z1 | c.123C>T p.T41= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100804237; called by muse, mutect2
- BMP3 | c.753G>A p.E251= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV51081781, COSV51085378; called by muse, mutect2, varscan2
- BOLA1 | c.87C>T p.I29= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV64967732; called by muse, mutect2, varscan2
- CCR8 | c.867C>A p.S289= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100413182; called by muse, mutect2, varscan2
- CD1B | c.396G>A p.L132= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as COSV100939302, COSV63805325; called by muse, mutect2, varscan2
- CEP164 | c.237C>T p.N79= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs149281923, COSV54047849; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLIC4 | c.759G>A p.K253= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs182652695; called by muse, mutect2, varscan2
- CPT1A | c.60C>T p.D20= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99681612; called by muse, mutect2
- DUSP4 | c.144G>A p.L48= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99529924; called by muse, mutect2, varscan2
- ERN1 | c.2538C>T p.S846= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs751720267, COSV101458571; called by muse, mutect2, varscan2
- FBXO8 | c.300C>T p.D100= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101183746; called by muse, mutect2, varscan2
- FCRL3 | c.612G>T p.G204= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100943551, COSV63840411; called by muse, mutect2
- GAK | c.3186A>T p.G1062= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100034066; called by muse, mutect2, varscan2
- HECTD4 | c.4551C>A p.V1517= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV101108378; called by muse, mutect2, varscan2
- KCNJ16 | c.852T>C p.Y284= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs371524728; called by muse, mutect2, varscan2
- P2RX7 | c.1032C>T p.F344= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs764035327, COSV55855489, COSV55857122; called by muse, mutect2, varscan2
- PITX1 | c.726C>A p.L242= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99530739; called by muse, mutect2, varscan2
- PRUNE2 | c.390G>A p.P130= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs763106333, COSV65030197; called by muse, mutect2, varscan2
- RAD54L2 | c.3525C>T p.I1175= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99621851; called by muse, mutect2, varscan2
- RNF213 | c.13815T>A p.I4605= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100301498; called by muse, mutect2, varscan2
- RRBP1 | c.3693A>G p.L1231= (on ENST00000377813 / NM_001365613.2; = p.L798= on NM_004587.3) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99854553; called by muse, mutect2
- RSBN1L | c.1011C>G p.L337= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1249488890, COSV100616232; called by muse, mutect2, varscan2
- SEC24D | c.33G>C p.P11= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV54884331, COSV99756827; called by muse, mutect2, varscan2
- SLC52A1 | c.927G>A p.G309= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99643539; called by muse, mutect2, varscan2
- SLCO1B1 | c.1161A>T p.A387= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99919147; called by muse, mutect2, varscan2
- SORT1 | c.1410G>A p.Q470= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99861139; called by muse, mutect2, varscan2
- TAF4 | c.2052G>A p.P684= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs200966805, COSV99434223; called by muse, mutect2
- TDRD1 | c.156T>C p.N52= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99315159; called by muse, mutect2, varscan2
- TFIP11 | c.1128C>A p.V376= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99314836; called by muse, mutect2, varscan2
- TGM2 | c.1311G>A p.E437= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100821762; called by muse, mutect2
- TPCN1 | c.1149C>T p.F383= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59241178; called by muse, mutect2
- TRHDE | c.2010A>C p.I670= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99672525; called by muse, mutect2, varscan2
- TUBA1A | c.96C>T p.P32= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs139102191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.4179C>T p.N1393= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs755627960, COSV99932844; called by muse, mutect2, varscan2
- UMODL1 | c.1995G>A p.R665= (on ENST00000408910 / NM_001004416.2; = p.R793= on NM_173568.3) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100210876; called by muse, mutect2, varscan2
- WDR59 | c.1188C>G p.S396= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100049730; called by muse, mutect2, varscan2
- ZFYVE9 | c.1968C>A p.I656= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV99820711; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899631 G>A | 3'Flank (SNP) | VAF 44/105 reads (42%) | catalogued as rs749270953; called by muse, mutect2, varscan2
